Gene-level copy-number profile of tumor specimen C3N-00580-03 from CPTAC case C3N-00580, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 56.8 years (20,730 days).
Specimen C3N-00580-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bca548ca-64e8-466d-a8c2-325ff3aa4328.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00580-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/f56c288f-e18a-4886-bcc9-8802e8d78029

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 511; copy number 1: 339; copy number 2: 5,588; copy number 3: 7,382; copy number 4: 14,436; copy number 5: 10,944; copy number 6: 11,492; copy number 7: 2,670; copy number 8: 5,162; copy number 9: 199; copy number 10: 8; copy number 12: 150; copy number 13: 31.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 388 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:48,066,393–49,246,915, 24 genes, copy number 10–12: TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4, AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22.
- chr4:51,843,000–66,431,521, 184 genes, copy number 9 (broad region; genes not listed).
- chr5:50,396,192–51,665,048, 21 genes, copy number 13: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2.
- chr8:63,013,068–71,815,625, 133 genes, copy number 12 (broad region; genes not listed).
- chr8:126,556,323–127,419,050, 1 gene, copy number 13 (within-gene range 8–13): PCAT1.
- chr8:127,072,694–127,742,951, 10 genes, copy number 10–13: CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC.
- chr9:63,974,762–64,737,755, 15 genes, copy number 9: AL163540.1, U6, ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2.

Autosomal genes at a single copy (total copy number 1): 327. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
